Somatic mutation profile of tumor specimen MMRF_1054_1_BM_CD138pos (aliquot MMRF_1054_1_BM_CD138pos_T1_KBS5U_L03479) from MMRF case MMRF_1054, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 58.3 years (21,310 days).
Specimen MMRF_1054_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 91cb3c15-10c4-4eeb-a10f-5a10f7a6c4a6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1054_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1054_1_PB_Whole_C2_KBS5U_L03491; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ba995e17-0c82-4aea-9a78-fc080b7f652c

The open-access MAF lists 65 somatic variants for this specimen: 26 protein-altering or splice-affecting, 8 silent, 31 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, 3'UTR 18, Silent 8, Intron 6, 5'UTR 2, 3'Flank 2, Nonsense Mutation 2, 5'Flank 2, Frame Shift Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 40/105 reads (38%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCC12 | c.163G>A p.A55T | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (0.34); PolyPhen benign (0.018); catalogued as rs773323570; called by muse, mutect2, varscan2
- ACSL6 | c.140G>A p.R47Q (on ENST00000379240; = p.R72Q on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.621); catalogued as rs551847044, COSV57296643; called by muse, mutect2, varscan2
- ASPG | c.194C>T p.P65L | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT tolerated (0.68); PolyPhen benign (0.005); catalogued as rs369717755, COSV101496337; called by muse, mutect2, varscan2
- AXIN1 | c.337G>A p.D113N | Missense Mutation (SNP) | VAF 5/97 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51986612, COSV51992449; called by muse, mutect2
- CFH | c.3016G>T p.D1006Y | Missense Mutation (SNP) | VAF 44/99 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.193); catalogued as COSV66405993; called by muse, mutect2, varscan2
- IGHV2-70 | c.188G>A p.G63E | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.911); catalogued as rs556768737; called by muse, varscan2
- IGHV2-70 | c.187G>A p.G63R | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.262); catalogued as rs764311666; called by muse, varscan2
- KALRN | c.5327G>A p.R1776H (on ENST00000360013 / NM_001024660.4; = p.R79H on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 59/143 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs368927353; called by muse, mutect2, varscan2
- MMP16 | c.191G>A p.R64H | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.26); catalogued as rs373603451; called by muse, mutect2, varscan2
- OR11H4 | c.494G>C p.G165A | Missense Mutation (SNP) | VAF 125/261 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.019); catalogued as rs765143524; called by muse, mutect2, varscan2
- PCNX2 | c.5818G>A p.V1940M | Missense Mutation (SNP) | VAF 28/42 reads (67%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); catalogued as rs779582742; called by muse, mutect2, varscan2
- RAPH1 | c.3524G>T p.R1175L | Missense Mutation (SNP) | VAF 50/107 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV55584462; called by muse, mutect2, varscan2
- TRPM3 | c.2213C>T p.T738M (on ENST00000357533 / NM_001366142.2; = p.T581M on NM_020952.6) | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs759218496, COSV62584720; called by muse, mutect2, varscan2
- FAM149A | c.433C>T p.L145F | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0.062); called by mutect2, varscan2
- IFIH1 | c.2825G>C p.R942T | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.982); called by muse, mutect2
- IGHJ4 | c.29del p.L10Rfs*? | Frame Shift Del (DEL) | VAF 30/44 reads (68%) | called by pindel, varscan2
- ITGAD | c.2986G>A p.E996K | Missense Mutation (SNP) | VAF 50/106 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- MAGEL2 | c.830C>T p.P277L | Missense Mutation (SNP) | VAF 40/97 reads (41%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- MIDEAS | c.745C>T p.Q249* | Nonsense Mutation (SNP) | VAF 17/45 reads (38%) | called by muse, varscan2
- MIDEAS | c.682C>T p.Q228* | Nonsense Mutation (SNP) | VAF 18/44 reads (41%) | called by muse, varscan2
- PHF6 | c.136A>C p.M46L | Missense Mutation (SNP) | VAF 60/104 reads (58%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- SCYL1 | c.1870C>G p.H624D | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT tolerated (0.7); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SIGLEC9 | c.1370C>G p.S457W | Missense Mutation (SNP) | VAF 50/102 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SOCS7 | c.970G>A p.D324N | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- TRAM2 | c.694A>G p.R232G | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.795); called by muse, mutect2, varscan2
- FOXO1 | c.123C>T p.S41= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as COSV101091906; called by muse, mutect2, varscan2
- NUP210 | c.5076C>T p.F1692= | Silent (SNP) | VAF 35/76 reads (46%) | catalogued as rs1328058996; called by muse, mutect2, varscan2
- OAZ3 | c.684C>T p.G228= | Silent (SNP) | VAF 22/59 reads (37%) | catalogued as rs554385707; called by muse, mutect2, varscan2
- PICALM | c.1800T>C p.Y600= | Silent (SNP) | VAF 15/138 reads (11%) | called by muse, mutect2, varscan2
- RASEF | c.1326C>A p.T442= | Silent (SNP) | VAF 49/93 reads (53%) | called by muse, mutect2, varscan2
- TRAF4 | c.1368C>G p.V456= | Silent (SNP) | VAF 60/126 reads (48%) | called by muse, mutect2, varscan2
- TRPM6 | c.894C>T p.N298= | Silent (SNP) | VAF 27/77 reads (35%) | catalogued as rs749889970, COSV62504905; called by muse, mutect2, varscan2
- UNC13D | c.2664C>T p.S888= | Silent (SNP) | VAF 4/57 reads (7%) | called by muse, mutect2
- ABCC9 | chr12:21800649 C>T | 3'Flank (SNP) | VAF 4/82 reads (5%) | called by muse, mutect2
- BCAR1 | c.*73C>T | 3'UTR (SNP) | VAF 3/13 reads (23%) | catalogued as rs909136271; called by muse, mutect2
- C1orf131 | c.747-120dup | Intron (INS) | VAF 31/94 reads (33%) | called by mutect2, pindel, varscan2
- CCND1 | c.*2182T>A | 3'UTR (SNP) | VAF 27/58 reads (47%) | called by muse, mutect2, varscan2
- CLNK | c.*1002A>T | 3'UTR (SNP) | VAF 21/49 reads (43%) | called by muse, mutect2, varscan2
- CLVS2 | c.-243T>A | 5'UTR (SNP) | VAF 19/53 reads (36%) | called by muse, mutect2, varscan2
- CSMD2 | c.6863-4817G>A | Intron (SNP) | VAF 22/60 reads (37%) | called by muse, mutect2, varscan2
- EEF1A1 | c.*790T>C | 3'UTR (SNP) | VAF 6/86 reads (7%) | catalogued as rs1267860289; called by muse, mutect2
- GABRA6 | c.39-49del | Intron (DEL) | VAF 31/80 reads (39%) | called by mutect2, pindel, varscan2
- HERPUD1 | c.*102A>T | 3'UTR (SNP) | VAF 51/115 reads (44%) | called by muse, mutect2, varscan2
- IFNA8 | c.*189G>A | 3'UTR (SNP) | VAF 43/96 reads (45%) | called by muse, mutect2, varscan2
- IGHV3-23 | c.-48T>C | 5'UTR (SNP) | VAF 20/68 reads (29%) | catalogued as rs781835581; called by muse, mutect2
- KLHL7 | c.*135A>G | 3'UTR (SNP) | VAF 9/132 reads (7%) | called by muse, mutect2
- MIR5195 | chr14:106851266 C>G | 5'Flank (SNP) | VAF 60/122 reads (49%) | catalogued as rs545752688; called by muse, varscan2
- OSGIN2 | c.*59T>C | 3'UTR (SNP) | VAF 31/85 reads (36%) | called by muse, mutect2, varscan2
- OSGIN2 | c.*306T>C | 3'UTR (SNP) | VAF 20/46 reads (43%) | called by muse, mutect2, varscan2
- OSGIN2 | c.*959A>T | 3'UTR (SNP) | VAF 89/186 reads (48%) | called by muse, mutect2, varscan2
- OSGIN2 | c.*1184A>G | 3'UTR (SNP) | VAF 26/63 reads (41%) | called by muse, mutect2, varscan2
- OSGIN2 | c.*1463A>C | 3'UTR (SNP) | VAF 50/102 reads (49%) | called by muse, mutect2, varscan2
- OSGIN2 | c.*1782A>C | 3'UTR (SNP) | VAF 48/101 reads (48%) | called by muse, mutect2, varscan2
- OSGIN2 | c.*2025A>C | 3'UTR (SNP) | VAF 52/104 reads (50%) | called by muse, mutect2, varscan2
- PLSCR1 | c.*351C>G | 3'UTR (SNP) | VAF 35/71 reads (49%) | called by muse, mutect2, varscan2
- PRMT8 | c.418-913G>A | Intron (SNP) | VAF 38/78 reads (49%) | catalogued as rs745476570; called by muse, mutect2, varscan2
- PRTG | c.*1816A>G | 3'UTR (SNP) | VAF 44/106 reads (42%) | called by muse, mutect2
- PTBP3 | chr9:112221869 T>A | 3'Flank (SNP) | VAF 39/100 reads (39%) | called by muse, mutect2, varscan2
- RPL13 | c.*1309dup | 3'UTR (INS) | VAF 24/60 reads (40%) | called by mutect2, varscan2
- SNORD115-4 | n.54T>A | RNA (SNP) | VAF 58/151 reads (38%) | called by muse, mutect2, varscan2
- SOS1 | c.*2403G>A | 3'UTR (SNP) | VAF 25/64 reads (39%) | called by muse, mutect2, varscan2
- TMSB4X | chrX:12975603 A>G | 5'Flank (SNP) | VAF 80/87 reads (92%) | called by muse, mutect2, varscan2
- TTC39A | c.1162-2273G>C | Intron (SNP) | VAF 97/212 reads (46%) | called by muse, mutect2, varscan2
- ZNF638 | c.2266-42T>A | Intron (SNP) | VAF 6/41 reads (15%) | called by muse, mutect2
